Somatic mutation profile of tumor specimen 0DX2D2 from CCDI case PBCPZR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 4.2 years (1,522 days).
Specimen 0DX2D2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8276fea5-4eb4-4bfd-8567-db50becd19a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX2CF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ba97cc4-b039-4683-9a81-fe9ce19cdb0e

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, 3'UTR 3, Splice Region 2, Silent 2, Intron 2, Translation Start Site 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLCN5 | c.724-1G>A p.X242_splice | Splice Site (SNP) | VAF 6/146 reads (4%) | catalogued as CS157826; called by muse, mutect2
- CTSE | c.1044C>T p.D348= (on ENST00000360218; = p.D343= on NM_001910.4) | Splice Region (SNP) | VAF 42/452 reads (9%) | catalogued as COSV100733634; called by muse, mutect2
- GTF2IRD2B | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 16/861 reads (2%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs587647388; called by muse, mutect2
- OR5H6 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 91/296 reads (31%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs1193470847; called by muse, mutect2, varscan2
- TMEM114 | c.350T>C p.M117T | Missense Mutation (SNP) | VAF 62/642 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.321); catalogued as rs889367924; called by muse, mutect2
- VPS13B | c.2783C>T p.T928I | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs1563641612; called by muse, mutect2
- ZNF713 | c.932G>A p.R311H (on ENST00000633730 / NM_001366796.2; = p.R324H on NM_182633.3) | Missense Mutation (SNP) | VAF 43/555 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs772724043, COSV70056566; called by muse, mutect2
- ANGPTL5 | c.815A>T p.K272I | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.223); called by muse, mutect2
- DRG1 | c.1016G>C p.W339S | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- EXOC8 | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- FER1L5 | c.5463G>C p.M1821I (on ENST00000623019; = p.M1785I on NM_001293083.2) | Missense Mutation (SNP) | VAF 38/465 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.053); called by muse, mutect2
- FERMT1 | c.1716C>G p.V572= | Splice Region (SNP) | VAF 17/298 reads (6%) | called by muse, mutect2
- NCKAP5 | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OTX2 | c.285A>C p.Q95H (on ENST00000408990 / NM_172337.3; = p.Q103H on NM_021728.4) | Missense Mutation (SNP) | VAF 91/190 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OTX2 | c.284A>G p.Q95R (on ENST00000408990 / NM_172337.3; = p.Q103R on NM_021728.4) | Missense Mutation (SNP) | VAF 90/188 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- UTS2B | c.89C>A p.P30Q | Missense Mutation (SNP) | VAF 89/209 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASAL1 | c.1305C>T p.P435= | Silent (SNP) | VAF 60/245 reads (24%) | catalogued as rs762206857; called by muse, mutect2, varscan2
- RYR2 | c.4026C>T p.D1342= | Silent (SNP) | VAF 18/526 reads (3%) | called by muse, mutect2
- C17orf107 | c.*684G>C | 3'UTR (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- ETV6 | c.*57G>A | 3'UTR (SNP) | VAF 9/114 reads (8%) | called by muse, mutect2
- GCSH | c.-79C>G | 5'UTR (SNP) | VAF 6/70 reads (9%) | catalogued as rs1029297241; called by muse, mutect2
- NDUFA13 | c.95-11T>G | Intron (SNP) | VAF 39/163 reads (24%) | catalogued as rs1201578530; called by muse, mutect2, varscan2
- NT5DC4 | c.299+54C>A | Intron (SNP) | VAF 6/118 reads (5%) | catalogued as rs1049676263; called by muse, mutect2
- SUSD4 | c.*1T>C | 3'UTR (SNP) | VAF 165/367 reads (45%) | catalogued as rs909148665; called by muse, mutect2, varscan2
